Somatic mutation profile of tumor specimen TCGA-DU-5851-01A (aliquot TCGA-DU-5851-01A-13D-1893-08) from TCGA case TCGA-DU-5851, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 40.5 years (14,802 days).
Specimen TCGA-DU-5851-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dba071f3-99e7-4c1d-bcb4-8c7f0d43a9d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-5851-10A (Blood Derived Normal), aliquot TCGA-DU-5851-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51138432-3d93-4a11-b8cf-b6ec1f72ad7c

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 7, Nonsense Mutation 2, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 27/106 reads (25%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AZIN2 | c.599G>C p.G200A | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV53855589; called by muse, mutect2, varscan2
- BORA | c.332A>C p.E111A (on ENST00000613797; = p.E36A on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/375 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as COSV64694789; called by muse, mutect2, varscan2
- BTNL8 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 85/467 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs766111997, COSV51456683, COSV51457621, COSV51462136; called by muse, mutect2, varscan2
- CCDC185 | c.1368C>A p.F456L | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as rs1558299196, COSV100838826, COSV64820159; called by muse, mutect2, varscan2
- COL24A1 | c.1211C>A p.T404K | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV65301041; called by muse, mutect2, varscan2
- FASTKD1 | c.13C>G p.P5A | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as COSV70006574; called by muse, mutect2, varscan2
- FCGR1A | c.278G>A p.S93N | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64985090, COSV64985501; called by muse, mutect2, varscan2
- H1-2 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1467030162, COSV59189525; called by muse, mutect2, varscan2
- IGSF10 | c.4742C>A p.S1581* | Nonsense Mutation (SNP) | VAF 22/217 reads (10%) | catalogued as COSV56781176; called by muse, mutect2, varscan2
- KANSL3 | c.2459G>A p.G820D (on ENST00000666923 / NM_001349262.2; = p.G794D on NM_001115016.3) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.243); catalogued as COSV62615574; called by muse, mutect2, varscan2
- MTCL1 | c.5085G>T p.K1695N (on ENST00000306329 / NM_001378206.1; = p.K1376N on NM_015210.4) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60402575; called by muse, mutect2, varscan2
- SAGE1 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 12/324 reads (4%) | catalogued as rs1556601244, COSV61011403; called by muse, mutect2
- SERPINB12 | c.242A>T p.K81I | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV54031966; called by muse, mutect2, varscan2
- WWC1 | c.2098G>A p.V700M | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs888661896, COSV54645190; called by muse, mutect2
- ZC3H12B | c.1025G>T p.S342I | Missense Mutation (SNP) | VAF 67/364 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV59046079; called by muse, mutect2, varscan2
- ATRX | c.1688_1692del p.L563Yfs*11 | Frame Shift Del (DEL) | VAF 89/403 reads (22%) | called by mutect2, pindel, varscan2
- MACF1 | c.11381G>T p.G3794V (on ENST00000372915; = p.G1727V on NM_012090.5) | Missense Mutation (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- CDH12 | c.2019C>T p.F673= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as rs775446101, COSV66385898; called by muse, mutect2, varscan2
- CTR9 | c.765C>T p.V255= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV63727639; called by muse, mutect2, varscan2
- GLIS3 | c.2313C>G p.V771= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV60923315; called by muse, mutect2, varscan2
- PLCXD3 | c.750C>A p.T250= | Silent (SNP) | VAF 44/191 reads (23%) | catalogued as COSV60603914; called by muse, mutect2, varscan2
- PPIF | c.504T>C p.H168= | Silent (SNP) | VAF 44/191 reads (23%) | catalogued as COSV56550813; called by muse, mutect2, varscan2
- RADIL | c.1932C>T p.S644= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs775702321, COSV67650800; called by muse, mutect2, varscan2
- SDK1 | c.5553G>T p.V1851= | Silent (SNP) | VAF 23/152 reads (15%) | catalogued as COSV67354772; called by muse, mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 7/58 reads (12%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- SYTL2 | c.1459+2757G>A | Intron (SNP) | VAF 23/116 reads (20%) | catalogued as rs764726291, COSV100314214; called by muse, mutect2, varscan2
